Somatic mutation profile of tumor specimen 0DZB1Z from CCDI case PBCTMF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.4 years (871 days).
Specimen 0DZB1Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0bad16b3-ecbf-40ae-bec7-2cca0e7202fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZB1M (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed1cd810-e244-429a-b2ea-ab1c0ee129de

The open-access MAF lists 9 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 2, Intron 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ITGA7 | c.182_183insTGCC p.Q61Hfs*43 | Frame Shift Ins (INS) | VAF 50/388 reads (13%) | called by pindel, varscan2
- PPIAL4C | c.331C>A p.Q111K | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); called by muse, varscan2
- SALL1 | c.1826C>A p.P609Q | Missense Mutation (SNP) | VAF 60/368 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.091); called by muse, varscan2
- KCNN1 | c.672C>T p.A224= | Silent (SNP) | VAF 78/189 reads (41%) | catalogued as rs1336784240; called by muse, varscan2
- MUC12 | c.5265C>A p.G1755= (on ENST00000379442; = p.G1612= on NM_001164462.1) | Silent (SNP) | VAF 34/394 reads (9%) | catalogued as rs1346102062; called by muse, varscan2
- NUP160 | c.4257C>T p.Y1419= | Silent (SNP) | VAF 192/641 reads (30%) | called by muse, varscan2
- PIEZO1 | c.4824C>A p.G1608= | Silent (SNP) | VAF 50/262 reads (19%) | catalogued as rs1408151717; called by muse, varscan2
- ROPN1L | c.593+70T>G | Intron (SNP) | VAF 48/119 reads (40%) | called by muse, varscan2
- SPRYD3 | c.*69T>G | 3'UTR (SNP) | VAF 69/343 reads (20%) | called by muse, varscan2
